Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3878, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3878-01A (Primary Tumor).

Diagnosis

This concerns sections of a moderately differentiated rectal carcinoma (colic adenocarcinoma in rectal position) with infiltration of the muscularis (pT2), without clear vascular infiltration (L0 V0), as well as free lymph nodes.

Tumor classification:

ICDO-DA M-8140/3

G2

pT2, L0, V0, pN0

Source: NCI Genomic Data Commons file 4d976b0a-45e4-4799-8c48-fab23b8819f8 (TCGA-AG-3878.1C22A9D6-937C-4D7B-9564-892999E0D4F6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).